Somatic mutation profile of tumor specimen TCGA-D3-A8GL-06A (aliquot TCGA-D3-A8GL-06A-11D-A372-08) from TCGA case TCGA-D3-A8GL, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 47.8 years (17,474 days).
Specimen TCGA-D3-A8GL-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8e56e201-a1a4-4ea9-8f72-52595483701c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A8GL-10A (Blood Derived Normal), aliquot TCGA-D3-A8GL-10A-01D-A375-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e9cb133-6261-431d-9f7e-9775c9bcad01

The open-access MAF lists 2,215 somatic variants for this specimen: 1,430 protein-altering or splice-affecting, 726 silent, 59 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,293, Silent 726, Nonsense Mutation 89, RNA 22, Intron 21, Splice Site 21, Splice Region 18, 3'UTR 6, 5'Flank 5, Translation Start Site 5, Frame Shift Del 4, 5'UTR 3.

Variants (750 of 2,215; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AR | c.2359C>T p.R787* | Nonsense Mutation (SNP) | VAF 35/38 reads (92%) | catalogued as rs1555997580, CM921000, COSV101019190, COSV101019783; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRIP1 | c.1794+1G>A p.X598_splice | Splice Site (SNP) | VAF 50/126 reads (40%) | catalogued as rs766516963, COSV99370827; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CNOT9 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 53/150 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs267599211, COSV55298957; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- COL1A2 | c.2567G>A p.G856E | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs886039689, CM090278, COSV99800786; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNAH8 | c.7981C>T p.R2661* | Nonsense Mutation (SNP) | VAF 25/96 reads (26%) | catalogued as rs149070832; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 67/127 reads (53%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- OTOF | c.5712+1G>A p.X1904_splice (on ENST00000272371 / NM_194248.3; = p.X1137_splice on NM_004802.4) | Splice Site (SNP) | VAF 15/35 reads (43%) | catalogued as rs80356604, COSV55506006; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTPRT | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 42/154 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61963254; called by muse, mutect2, varscan2
- AADACL4 | c.131G>A p.R44K | Missense Mutation (SNP) | VAF 98/189 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.391); catalogued as COSV100879491; called by muse, mutect2, varscan2
- AARS2 | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 100/145 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99771634; called by muse, mutect2, varscan2
- ABCA12 | c.6629C>T p.S2210F (on ENST00000272895 / NM_173076.3; = p.S1892F on NM_015657.3) | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV55961716; called by muse, mutect2, varscan2
- ABCA13 | c.12155T>G p.L4052R | Missense Mutation (SNP) | VAF 59/117 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101447158; called by muse, mutect2, varscan2
- ABCA6 | c.103G>C p.G35R | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.449); catalogued as COSV99447468; called by muse, mutect2, varscan2
- ABCA9 | c.1907C>T p.P636L | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100383399, COSV100383490; called by muse, mutect2, varscan2
- ABCB4 | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV55933743; called by muse, mutect2, varscan2
- ABCB5 | c.2701G>A p.E901K (on ENST00000404938 / NM_001163941.2; = p.E456K on NM_178559.6) | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.06); catalogued as rs771565914, COSV99329323; called by muse, mutect2, varscan2
- ABCB5 | c.3052C>T p.R1018* (on ENST00000404938 / NM_001163941.2; = p.R573* on NM_178559.6) | Nonsense Mutation (SNP) | VAF 16/45 reads (36%) | catalogued as rs200343372; called by muse, mutect2, varscan2
- ABCC2 | c.3503C>T p.S1168L | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0.226); catalogued as COSV100966361, COSV100966669; called by muse, mutect2, varscan2
- ABCD4 | c.538C>T p.Q180* | Nonsense Mutation (SNP) | VAF 30/61 reads (49%) | catalogued as COSV53995258; called by muse, mutect2, varscan2
- ABCF3 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.635); catalogued as COSV99490888; called by muse, mutect2, varscan2
- ABI3BP | c.1196C>T p.S399F | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs867423502, COSV99428262; called by muse, mutect2, varscan2
- ABLIM2 | c.1490G>A p.R497K (on ENST00000341937 / NM_001130084.2; = p.R446K on NM_032432.5) | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as COSV99590314; called by muse, mutect2, varscan2
- ABRAXAS2 | c.578+1G>A p.X193_splice | Splice Site (SNP) | VAF 32/75 reads (43%) | catalogued as COSV100045090; called by muse, mutect2, varscan2
- AC011455.2 | c.1117G>A p.G373R | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1235439588, COSV99671514; called by muse, mutect2, varscan2
- AC104452.1 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1302924709, COSV99864730; called by muse, mutect2, varscan2
- ACAD10 | c.2116G>A p.E706K | Missense Mutation (SNP) | VAF 29/33 reads (88%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.784); catalogued as COSV100564525; called by muse, mutect2, varscan2
- ACKR1 | c.524G>A p.G175E | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.973); catalogued as COSV63672135; called by muse, mutect2, varscan2
- ACSM1 | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as COSV54633527; called by muse, mutect2, varscan2
- ACSM1 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as COSV54637157; called by muse, mutect2, varscan2
- ACSM2A | c.407G>A p.G136E (on ENST00000219054; = p.G57E on NM_001308169.2) | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99525632; called by muse, mutect2, varscan2
- ACSM2B | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs1191705830, COSV100313056; called by muse, mutect2, varscan2
- ACSM4 | c.1112G>A p.G371E | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68068644; called by muse, mutect2, varscan2
- ACSM4 | c.1577C>T p.S526F | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV101257311; called by muse, mutect2, varscan2
- ADAM18 | c.1646G>A p.G549E | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748944460, COSV55858283; called by muse, mutect2, varscan2
- ADAM18 | c.1852C>T p.H618Y | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0.296); catalogued as rs866076661, COSV55845988; called by muse, mutect2, varscan2
- ADAM20 | c.2101C>T p.P701S | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV56457247; called by muse, mutect2
- ADAM30 | c.1987G>A p.E663K | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV101023958; called by muse, mutect2, varscan2
- ADAM7 | c.416G>T p.R139I | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51544935, COSV99444815; called by muse, mutect2, varscan2
- ADAMTS12 | c.2680T>G p.C894G | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100711555; called by muse, varscan2
- ADAMTS14 | c.1906C>T p.P636S | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1328124533, COSV64603843; called by muse, mutect2, varscan2
- ADAMTS18 | c.3043G>A p.E1015K | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT tolerated (0.84); PolyPhen benign (0.102); catalogued as rs1461358945, COSV99273882; called by muse, mutect2, varscan2
- ADAMTS18 | c.2332G>A p.E778K | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0.322); catalogued as rs779170683, COSV51399738; called by muse, mutect2, varscan2
- ADAMTS18 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs770516167, COSV51399705; called by muse, mutect2, varscan2
- ADAMTS20 | c.5633G>A p.R1878Q | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs779950063, COSV67136601, COSV67137684; called by muse, mutect2, varscan2
- ADAMTS5 | c.547G>A p.G183R | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV99538213; called by muse, mutect2
- ADAMTS9 | c.5566C>T p.P1856S | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55792803; called by muse, mutect2, varscan2
- ADAR | c.2368C>T p.R790C | Missense Mutation (SNP) | VAF 85/115 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1429411421, COSV99426584; called by muse, mutect2, varscan2
- ADARB2 | c.368C>T p.S123L | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); catalogued as rs780511733, COSV101187190; called by muse, mutect2, varscan2
- ADCY1 | c.1020G>A p.T340= | Splice Region (SNP) | VAF 14/26 reads (54%) | catalogued as rs775492975, COSV99812760; called by muse, varscan2
- ADGRB3 | c.3532C>T p.P1178S | Missense Mutation (SNP) | VAF 50/51 reads (98%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV53238942, COSV53247980; called by muse, mutect2, varscan2
- ADGRE2 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1321030202, COSV100216431; called by muse, mutect2, varscan2
- ADGRF5 | c.1749T>G p.S583R | Missense Mutation (SNP) | VAF 46/74 reads (62%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV99346265; called by muse, mutect2, varscan2
- ADGRG4 | c.6704C>T p.S2235L | Missense Mutation (SNP) | VAF 44/48 reads (92%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs749693269, COSV54950917; called by muse, mutect2, varscan2
- ADGRL3 | c.3088G>A p.G1030R (on ENST00000506720 / NM_001322402.2; = p.G962R on NM_015236.6) | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101547358; called by muse, mutect2, varscan2
- ADGRV1 | c.6892G>A p.E2298K | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV101316360; called by muse, mutect2, varscan2
- ADGRV1 | c.16664C>T p.S5555F | Missense Mutation (SNP) | VAF 57/107 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV101316361; called by muse, mutect2, varscan2
- ADH1A | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 54/120 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.19); catalogued as COSV52926169; called by muse, varscan2
- ADPRHL1 | c.556G>A p.G186R | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.919); catalogued as COSV100733518, COSV100733520; called by muse, mutect2, varscan2
- ADPRM | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 38/44 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100541442; called by muse, mutect2, varscan2
- ADTRP | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV99995444; called by muse, mutect2, varscan2
- AFF2 | c.2806C>T p.P936S | Missense Mutation (SNP) | VAF 22/25 reads (88%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782296499, COSV99665793; called by muse, mutect2, varscan2
- AGXT2 | c.1088C>A p.T363N | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99183859; called by muse, mutect2, varscan2
- AHNAK | c.17299A>G p.K5767E | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV99949147; called by muse, mutect2, varscan2
- AHNAK | c.15557C>T p.S5186F | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs758017546, COSV99949149; called by muse, mutect2, varscan2
- AHNAK2 | c.12805G>A p.E4269K | Missense Mutation (SNP) | VAF 121/282 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as rs755133395, COSV60913165; called by muse, varscan2
- AJM1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99915863; called by muse, mutect2, varscan2
- AK2 | c.326C>T p.S109F (on ENST00000354858; = p.S151F on NM_001625.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 117/244 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV100710057; called by muse, mutect2, varscan2
- AKAP11 | c.2986A>G p.T996A | Missense Mutation (SNP) | VAF 49/89 reads (55%) | SIFT tolerated (0.57); PolyPhen benign (0.011); catalogued as COSV99214250; called by muse, mutect2, varscan2
- AKR1B1 | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99605380; called by muse, mutect2, varscan2
- AKR1C4 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as COSV99578532; called by muse, mutect2, varscan2
- AL121899.2 | c.1145G>A p.G382E | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101198625; called by muse, mutect2, varscan2
- ALB | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 58/113 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.404); catalogued as COSV55742927; called by muse, mutect2, varscan2
- ALDH8A1 | c.1147G>A p.D383N | Missense Mutation (SNP) | VAF 37/43 reads (86%) | SIFT tolerated (0.18); PolyPhen benign (0.034); catalogued as COSV99664534; called by muse, mutect2, varscan2
- AMER3 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100366825; called by muse, mutect2, varscan2
- AMN | c.64A>G p.K22E | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100141569; called by muse, mutect2, varscan2
- ANGPT1 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as COSV99863825; called by muse, mutect2, varscan2
- ANK3 | c.12005G>A p.G4002E | Missense Mutation (SNP) | VAF 78/142 reads (55%) | SIFT tolerated, low confidence (0.51); PolyPhen possibly damaging (0.702); catalogued as COSV99781858; called by muse, mutect2, varscan2
- ANK3 | c.8506C>T p.H2836Y | Missense Mutation (SNP) | VAF 74/142 reads (52%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.018); catalogued as rs199656517, COSV99781862; called by muse, mutect2, varscan2
- ANK3 | c.7786C>T p.R2596C | Missense Mutation (SNP) | VAF 60/135 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55053162; called by muse, mutect2, varscan2
- ANKFN1 | c.1934A>T p.N645I | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100594037; called by muse, mutect2, varscan2
- ANKK1 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs780936187, COSV58271631; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD10 | c.863C>T p.S288F | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.459); catalogued as COSV99941254; called by muse, mutect2, varscan2
- ANKRD30A | c.805C>T p.Q269* (on ENST00000611781; = p.Q213* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 12/31 reads (39%) | catalogued as rs1435688063, COSV100653701, COSV100654274; called by muse, mutect2, varscan2
- ANKRD30A | c.1155G>A p.W385* (on ENST00000611781; = p.W329* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 45/108 reads (42%) | catalogued as rs759835090, COSV100654276; called by muse, mutect2, varscan2
- ANKRD30A | c.1697G>A p.W566* (on ENST00000611781; = p.W510* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 87/193 reads (45%) | catalogued as COSV100654277; called by muse, mutect2, varscan2
- ANKRD30A | c.2125G>A p.E709K (on ENST00000611781; = p.E653K on NM_052997.2) | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.678); catalogued as COSV100654280; called by muse, mutect2, varscan2
- ANKRD30A | c.3933A>T p.K1311N (on ENST00000611781; = p.K1255N on NM_052997.2) | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); catalogued as COSV100654282; called by muse, mutect2, varscan2
- ANKRD35 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as COSV100841831; called by muse, mutect2, varscan2
- ANKRD35 | c.1189C>T p.P397S | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as COSV62912149; called by muse, mutect2, varscan2
- ANKRD45 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 95/126 reads (75%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.622); catalogued as COSV100322639; called by muse, mutect2, varscan2
- ANO3 | c.2453G>A p.G818E | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99885076; called by muse, mutect2, varscan2
- ANO4 | c.2491C>T p.R831* (on ENST00000392977 / NM_001286615.2; = p.R796* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 54/61 reads (89%) | catalogued as rs145182702, COSV54586547; called by muse, mutect2, varscan2
- ANO6 | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 70/149 reads (47%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100263755; called by muse, mutect2, varscan2
- ANP32D | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV99874378; called by muse, mutect2, varscan2
- AOC1 | c.1147C>T p.H383Y | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT tolerated (0.71); PolyPhen benign (0.02); catalogued as COSV62868727; called by muse, mutect2, varscan2
- AP002512.3 | c.1055C>T p.S352F | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV54406363; called by muse, mutect2, varscan2
- APBA2 | c.2182C>T p.H728Y | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs755974076, COSV99723217; called by muse, mutect2, varscan2
- APLF | c.1111G>A p.G371R | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV100376962; called by muse, mutect2, varscan2
- APOB | c.10374G>A p.M3458I | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51955902; called by muse, mutect2, varscan2
- APOB | c.7750G>A p.G2584R | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1558563314, COSV51927201, COSV99267392; called by muse, mutect2, varscan2
- APOF | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 46/82 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as rs754882582, COSV100029094; called by muse, mutect2, varscan2
- AQP6 | c.767G>A p.G256E | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59646912; called by muse, mutect2, varscan2
- AREG | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 109/247 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.069); catalogued as COSV99144399; called by muse, mutect2, varscan2
- ARFGEF3 | c.1430C>T p.A477V | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs1469626399, COSV99294484; called by muse, mutect2, varscan2
- ARFGEF3 | c.5803G>A p.D1935N | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs771537463, COSV52475520; called by muse, mutect2, varscan2
- ARHGAP21 | c.3754C>T p.P1252S | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.952); catalogued as COSV100256566; called by muse, mutect2, varscan2
- ARHGAP29 | c.1679C>T p.P560L | Missense Mutation (SNP) | VAF 58/113 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV99558777, COSV99558865; called by muse, mutect2, varscan2
- ARHGAP29 | c.560G>A p.G187E | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as rs1490725729, COSV53110053; called by muse, mutect2, varscan2
- ARHGAP36 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 51/55 reads (93%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV52265981, COSV52270515; called by muse, mutect2, varscan2
- ARHGEF11 | c.1741C>T p.P581S | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.243); catalogued as rs368035698; called by muse, mutect2, varscan2
- ARHGEF17 | c.3640C>T p.P1214S | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99736549; called by muse, mutect2, varscan2
- ARHGEF17 | c.5731G>A p.D1911N | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV55234514; called by muse, mutect2, varscan2
- ARHGEF3 | c.766C>T p.L256F | Missense Mutation (SNP) | VAF 69/149 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99575848; called by muse, mutect2, varscan2
- ARID2 | c.1805G>A p.R602K | Missense Mutation (SNP) | VAF 98/205 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); catalogued as COSV100536846, COSV57603528; called by muse, mutect2, varscan2
- ARID2 | c.2975C>A p.S992Y | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.146); catalogued as COSV100536847; called by muse, mutect2, varscan2
- ARMC4 | c.2440C>T p.L814F | Missense Mutation (SNP) | VAF 56/124 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100537275, COSV59459546; called by muse, mutect2, varscan2
- ASB15 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 45/84 reads (54%) | SIFT tolerated (0.38); PolyPhen benign (0.019); catalogued as rs267601260, COSV99306913; called by muse, mutect2, varscan2
- ASCC3 | c.2773C>T p.R925W | Missense Mutation (SNP) | VAF 51/57 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371587845; called by muse, mutect2, varscan2
- ASH1L | c.4348G>A p.E1450K | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.681); catalogued as COSV100853571; called by muse, mutect2, varscan2
- ASTN1 | c.1550G>A p.R517Q | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.187); catalogued as rs370485432; called by muse, mutect2, varscan2
- ASXL2 | c.922C>T p.P308S | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55456278, COSV55462264; called by muse, mutect2, varscan2
- ASXL3 | c.642G>A p.M214I | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.366); catalogued as COSV52483827; called by mutect2, varscan2
- ASXL3 | c.1750C>T p.P584S | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.02); catalogued as COSV52464752; called by muse, mutect2, varscan2
- ASXL3 | c.4469C>A p.S1490Y | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); catalogued as COSV99326161; called by muse, mutect2, varscan2
- ATAD2 | c.1757G>A p.R586K | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99785157; called by muse, mutect2, varscan2
- ATAD2B | c.2519G>A p.W840* | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | catalogued as COSV99478309; called by muse, mutect2, varscan2
- ATP13A2 | c.1087C>T p.P363S | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV100454379; called by muse, mutect2, varscan2
- ATP1A4 | c.1931C>T p.T644I | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.315); catalogued as COSV100927628; called by muse, mutect2, varscan2
- ATP8A1 | c.2694+1G>A p.X898_splice | Splice Site (SNP) | VAF 45/101 reads (45%) | catalogued as COSV100047138; called by muse, mutect2, varscan2
- AUTS2 | c.1937C>T p.P646L | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100719334; called by muse, mutect2, varscan2
- AVPR1B | c.21G>A p.W7* | Nonsense Mutation (SNP) | VAF 368/503 reads (73%) | catalogued as COSV100899440; called by muse, mutect2, varscan2
- BANK1 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs770184787, COSV59845564; called by muse, mutect2, varscan2
- BCL2L11 | c.421G>A p.D141N (on ENST00000393256 / NM_138621.5; = p.D81N on NM_006538.5) | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.21); catalogued as COSV100427463; called by muse, mutect2, varscan2
- BDKRB1 | c.667T>C p.Y223H | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.796); catalogued as COSV99388006; called by muse, mutect2, varscan2
- BEND4 | c.1238G>A p.R413Q | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.998); catalogued as COSV101549775; called by muse, mutect2, varscan2
- BIRC6 | c.6076A>T p.I2026F | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as COSV101428659; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.254C>A p.T85N | Missense Mutation (SNP) | VAF 72/126 reads (57%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.51); catalogued as COSV99959044; called by muse, mutect2, varscan2
- BMP2K | c.1711T>C p.F571L | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.294); catalogued as COSV100621925; called by muse, mutect2, varscan2
- BMP3 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as rs370097482, COSV51081598; called by muse, mutect2, varscan2
- BMP7 | c.460C>T p.R154* | Nonsense Mutation (SNP) | VAF 46/145 reads (32%) | catalogued as rs1261883272, COSV101216221; called by muse, mutect2, varscan2
- BNC1 | c.1193C>T p.S398F | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100597425; called by muse, mutect2, varscan2
- BOC | c.638C>T p.S213F | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99849268; called by muse, mutect2, varscan2
- BOD1L1 | c.4594C>T p.P1532S | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV99240156; called by muse, mutect2, varscan2
- BPIFB1 | c.1140C>T p.I380= | Splice Region (SNP) | VAF 64/97 reads (66%) | catalogued as rs6088166; called by muse, mutect2, varscan2
- BPIFB3 | c.475C>T p.L159F | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs1299131316, COSV100972405; called by muse, mutect2, varscan2
- BRINP2 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100838303, COSV64177289; called by muse, mutect2, varscan2
- BRINP2 | c.1442A>G p.N481S | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as rs1179571671, COSV100838304, COSV64176218; called by muse, mutect2, varscan2
- BSN | c.10607C>T p.S3536F | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56518099; called by muse, mutect2, varscan2
- BTBD11 | c.2168G>A p.G723E (on ENST00000280758 / NM_001018072.2; = p.G260E on NM_001017523.2) | Missense Mutation (SNP) | VAF 24/28 reads (86%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55021625; called by muse, mutect2, varscan2
- C10orf120 | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.171); catalogued as COSV61492912; called by muse, mutect2, varscan2
- C10orf71 | c.371G>A p.R124K | Missense Mutation (SNP) | VAF 41/71 reads (58%) | SIFT tolerated (0.47); PolyPhen benign (0.095); catalogued as rs749704649, COSV100110569; called by muse, mutect2, varscan2
- C12orf40 | c.182C>T p.S61F | Missense Mutation (SNP) | VAF 53/130 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100210608; called by muse, mutect2, varscan2
- C15orf39 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 138/209 reads (66%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.732); catalogued as rs868051066, COSV62296770; called by muse, mutect2, varscan2
- C1QTNF9 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.099); catalogued as COSV100130003; called by muse, mutect2, varscan2
- C1orf116 | c.514C>T p.Q172* | Nonsense Mutation (SNP) | VAF 74/112 reads (66%) | catalogued as COSV100848002; called by muse, mutect2, varscan2
- C1orf210 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs374573587; called by muse, mutect2, varscan2
- C1orf56 | c.347G>A p.G116E | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.085); catalogued as COSV99764770; called by muse, mutect2, varscan2
- C2CD3 | c.2236C>T p.P746S | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.584); catalogued as rs148286994, COSV100487255; called by muse, mutect2, varscan2
- C2orf16 | c.2493G>A p.M831I | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV62675794; called by muse, mutect2, varscan2
- C2orf78 | c.2051C>T p.P684L | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.766); catalogued as rs756767934, COSV101280987, COSV68518293; called by muse, mutect2, varscan2
- C6 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867222895, COSV54718556; called by muse, mutect2, varscan2
- C6 | c.230G>A p.R77K | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs762327241, COSV54705765, COSV54706317; called by muse, mutect2, varscan2
- C7 | c.1753G>A p.E585K | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as COSV100496449; called by muse, mutect2, varscan2
- C8A | c.1081A>T p.K361* | Nonsense Mutation (SNP) | VAF 40/101 reads (40%) | catalogued as COSV100776653; called by muse, mutect2, varscan2
- C8A | c.1640C>T p.S547F | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.937); catalogued as COSV100776654; called by muse, mutect2, varscan2
- C8B | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.078); catalogued as rs770507328, COSV64777350; called by muse, mutect2
- CA1 | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs1429758308, COSV99810312; called by muse, mutect2, varscan2
- CA1 | c.372G>A p.W124* | Nonsense Mutation (SNP) | VAF 22/49 reads (45%) | catalogued as COSV99810241; called by muse, mutect2, varscan2
- CACNA1B | c.4975G>A p.E1659K | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs745458852, COSV53124332, COSV53145854; called by muse, mutect2, varscan2
- CACNA1C | c.1024G>A p.G342S | Missense Mutation (SNP) | VAF 195/297 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100221649; called by muse, mutect2, varscan2
- CACNA1D | c.3756G>A p.M1252I (on ENST00000350061 / NM_001128840.3; = p.M1272I on NM_000720.4) | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV99859627; called by muse, mutect2, varscan2
- CACNA1E | c.6293C>T p.S2098F (on ENST00000367573 / NM_001205293.3; = p.S2055F on NM_000721.4) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs764537662, COSV100704711; called by muse, mutect2, varscan2
- CACNA1G | c.1771C>T p.P591S | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as rs771214256, COSV100662383; ClinVar: uncertain significance; called by muse, varscan2
- CACNA1S | c.1519G>A p.G507S | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.98); catalogued as rs554729466, COSV62941154; called by muse, mutect2, varscan2
- CACNA2D1 | c.2234C>T p.P745L (on ENST00000356253 / NM_001366867.1; = p.P733L on NM_000722.4) | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV100667032, COSV100667092; called by muse, mutect2, varscan2
- CACNB4 | c.1531G>A p.G511R | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.445); catalogued as COSV99139257; called by muse, mutect2, varscan2
- CADPS | c.3901C>T p.R1301* | Nonsense Mutation (SNP) | VAF 25/68 reads (37%) | catalogued as rs141301525, COSV51881188; called by muse, mutect2, varscan2
- CADPS | c.2153G>A p.R718Q | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1345515862, COSV51879695; called by muse, mutect2, varscan2
- CADPS | c.1928G>A p.G643E | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.554); catalogued as COSV51872873; called by muse, mutect2, varscan2
- CALB2 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 99/237 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.416); catalogued as COSV100226461, COSV56940629; called by muse, mutect2, varscan2
- CAMK1D | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as COSV66608909; called by muse, mutect2, varscan2
- CAMSAP2 | c.1971T>A p.F657L (on ENST00000236925 / NM_001297707.2; = p.F646L on NM_203459.3) | Missense Mutation (SNP) | VAF 47/184 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV99374118; called by muse, mutect2, varscan2
- CASP1 | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 118/281 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.248); catalogued as COSV100782834; called by muse, mutect2, varscan2
- CASP14 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55665737; called by muse, mutect2, varscan2
- CASZ1 | c.2611G>A p.G871S | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as rs139084217; called by muse, mutect2, varscan2
- CATSPERB | c.443G>A p.G148E | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1566737150, COSV56438701; called by muse, varscan2
- CBX2 | c.1565C>T p.T522I | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs868916040, COSV99490989, COSV99491066; called by muse, mutect2, varscan2
- CCDC142 | c.1794C>T p.F598= (on ENST00000393965 / NM_001365575.2; = p.F591= on NM_032779.4) | Splice Region (SNP) | VAF 52/108 reads (48%) | catalogued as COSV99252216; called by muse, mutect2, varscan2
- CCDC173 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.021); catalogued as rs1292262836, COSV101470198; called by muse, mutect2, varscan2
- CCDC185 | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs758987357, COSV100838829, COSV64821743; called by muse, mutect2, varscan2
- CCDC186 | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs1408430268, COSV100991136; called by muse, mutect2, varscan2
- CCDC68 | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 32/81 reads (40%) | catalogued as COSV100491976; called by muse, mutect2, varscan2
- CCDC71 | c.1147C>T p.P383S | Missense Mutation (SNP) | VAF 63/111 reads (57%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV100422428; called by muse, mutect2, varscan2
- CCDC89 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT tolerated (0.57); PolyPhen benign (0.066); catalogued as rs1382064760, COSV100320910; called by muse, mutect2, varscan2
- CCR1 | c.19A>T p.T7S | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs200097434, COSV99946790; called by muse, mutect2, varscan2
- CCSER1 | c.1924C>T p.L642F | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61473145; called by muse, mutect2, varscan2
- CCSER2 | c.453A>T p.K151N | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV99826365; called by muse, mutect2, varscan2
- CCT8L2 | c.632G>A p.G211E | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as COSV63461779; called by muse, mutect2, varscan2
- CD1A | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 39/204 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as rs752354521, COSV56860895; called by muse, mutect2, varscan2
- CD22 | c.2321G>A p.R774Q | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.044); catalogued as rs143516468; called by muse, mutect2, varscan2
- CD3G | c.215G>A p.W72* | Nonsense Mutation (SNP) | VAF 21/55 reads (38%) | catalogued as COSV99416864; called by muse, mutect2, varscan2
- CDC5L | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 80/142 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101015161; called by muse, mutect2, varscan2
- CDH11 | c.352C>T p.R118* | Nonsense Mutation (SNP) | VAF 24/49 reads (49%) | catalogued as COSV51760422; called by muse, mutect2, varscan2
- CDH13 | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 71/145 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99221744, COSV99227491; called by muse, mutect2, varscan2
- CDH18 | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as rs1486870265, COSV56932538; called by muse, mutect2, varscan2
- CDH20 | c.466C>T p.Q156* | Nonsense Mutation (SNP) | VAF 15/41 reads (37%) | catalogued as COSV99406332; called by muse, mutect2, varscan2
- CDH20 | c.548C>A p.S183Y | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as COSV53004926, COSV99406335; called by muse, mutect2, varscan2
- CDH20 | c.1694A>C p.Q565P | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as COSV99406337; called by muse, mutect2, varscan2
- CDH22 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.653); catalogued as rs1444758369, COSV100952967; called by muse, mutect2, varscan2
- CDH23 | c.9512G>A p.G3171E | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1321844333, COSV56452343; called by muse, mutect2, varscan2
- CDH6 | c.102G>T p.K34N | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV54071593, COSV99420532; called by muse, mutect2, varscan2
- CDH9 | c.2122G>A p.E708K | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.491); catalogued as rs867901234, COSV50264302, COSV50324297; called by muse, mutect2, varscan2
- CDHR2 | c.1343C>G p.A448G | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as COSV99992091; called by muse, varscan2
- CDK3 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as rs1424386342, COSV56906683; called by muse, mutect2
- CDKL4 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs147480081, COSV101115488; called by muse, mutect2, varscan2
- CDON | c.665T>A p.I222N | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV99701862; called by muse, mutect2, varscan2
- CEACAM20 | c.118G>A p.D40N | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1357729797, COSV57601222; called by muse, mutect2, varscan2
- CEACAM4 | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99701173; called by muse, mutect2, varscan2
- CEBPE | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.585); catalogued as COSV99247639; called by muse, mutect2, varscan2
- CELF4 | c.938C>T p.T313I | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.615); catalogued as COSV100611922, COSV58461150; called by muse, mutect2, varscan2
- CEP170 | c.4030C>T p.P1344S | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1290296771, COSV100317699; called by muse, mutect2, varscan2
- CEP192 | c.3947C>T p.S1316L | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV100381914; called by muse, mutect2, varscan2
- CEP57L1 | c.953C>T p.S318F | Missense Mutation (SNP) | VAF 55/66 reads (83%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as COSV100425946; called by muse, mutect2, varscan2
- CERKL | c.799C>T p.H267Y (on ENST00000339098 / NM_001030311.2; = p.H241Y on NM_201548.5) | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs770502010, COSV59209612; called by muse, mutect2, varscan2
- CFAP43 | c.423G>A p.W141* | Nonsense Mutation (SNP) | VAF 23/39 reads (59%) | catalogued as rs1376343468, COSV53377030, COSV99530948; called by muse, mutect2, varscan2
- CFAP52 | c.1575G>A p.K525= | Splice Region (SNP) | VAF 16/18 reads (89%) | catalogued as COSV100235512; called by muse, mutect2, varscan2
- CFAP58 | c.2119C>T p.P707S | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs1193449263, COSV100866144, COSV63834477; called by muse, mutect2, varscan2
- CFH | c.212G>A p.W71* | Nonsense Mutation (SNP) | VAF 25/130 reads (19%) | catalogued as COSV100661601; called by muse, mutect2, varscan2
- CFH | c.2539G>A p.E847K | Missense Mutation (SNP) | VAF 57/118 reads (48%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.771); catalogued as COSV100810032, COSV66412097; called by muse, mutect2, varscan2
- CGB2 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.994); catalogued as COSV56820171; called by muse, mutect2, varscan2
- CHD4 | c.4551G>T p.M1517I (on ENST00000357008 / NM_001363606.2; = p.M1530I on NM_001273.5) | Missense Mutation (SNP) | VAF 89/165 reads (54%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV100538938; called by muse, mutect2, varscan2
- CHGB | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1384050974, COSV100973066; called by muse, mutect2, varscan2
- CHRNB4 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99929551; called by muse, mutect2, varscan2
- CHRND | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.24); catalogued as COSV99286096; called by muse, mutect2, varscan2
- CIITA | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.202); catalogued as rs780678285, COSV100161847; called by muse, mutect2, varscan2
- CLASP1 | c.2063C>T p.S688F | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99756749; called by muse, mutect2, varscan2
- CLCA2 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs1260895477, COSV100991678; called by muse, mutect2
- CLCN1 | c.2887G>A p.E963K | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.129); catalogued as rs1290059380, COSV100578430; called by muse, mutect2, varscan2
- CLDN14 | c.468G>A p.M156I | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as COSV59774045; called by muse, mutect2, varscan2
- CLEC16A | c.3031C>T p.P1011S | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.979); catalogued as COSV55490227; called by muse, mutect2, varscan2
- CLEC6A | c.511C>T p.H171Y | Missense Mutation (SNP) | VAF 62/191 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV101165699, COSV65987765; called by muse, mutect2, varscan2
- CLEC7A | c.518C>T p.S173F (on ENST00000304084 / NM_197947.3; = p.S127F on NM_022570.5) | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); catalogued as rs1462311040, COSV53723984, COSV53724066; called by muse, mutect2, varscan2
- CLPB | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs1251647670, COSV53630585; called by muse, mutect2, varscan2
- CLSTN2 | c.2632G>A p.D878N | Missense Mutation (SNP) | VAF 53/89 reads (60%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as rs1380076789, COSV71717618; called by muse, mutect2, varscan2
- CLSTN3 | c.2309G>A p.G770E | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.299); catalogued as COSV99867564; called by muse, mutect2, varscan2
- CNGA1 | c.209G>T p.G70V | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV100652311; called by muse, mutect2, varscan2
- CNGB3 | c.2018C>T p.P673L | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1469701059, COSV100182859; called by muse, mutect2, varscan2
- CNST | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 60/280 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs376090886; called by muse, mutect2, varscan2
- CNTN5 | c.2233G>A p.E745K | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54341795; called by muse, varscan2
- CNTN5 | c.2264G>A p.G755E | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1351618548, COSV99680317; called by muse, varscan2
- CNTN5 | c.2467G>C p.E823Q | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); catalogued as rs1385144818, COSV54282815, COSV99680319; called by muse, mutect2, varscan2
- CNTNAP2 | c.1085G>A p.G362E | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as COSV62144663, COSV62167074; called by muse, mutect2, varscan2
- CNTNAP4 | c.2185A>T p.N729Y | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.203); catalogued as COSV100272888; called by muse, mutect2, varscan2
- CNTNAP5 | c.2753G>A p.G918E | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs762966870, COSV101443996, COSV70510268; called by muse, mutect2, varscan2
- COL19A1 | c.1402G>A p.G468R | Missense Mutation (SNP) | VAF 57/71 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1292226287, COSV59587665; called by muse, mutect2, varscan2
- COL19A1 | c.2251G>A p.E751K | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs144357283; called by muse, mutect2, varscan2
- COL1A2 | c.3448C>T p.L1150F | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99800790; called by muse, mutect2, varscan2
- COL21A1 | c.2546G>A p.G849E | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV99779335; called by muse, mutect2, varscan2
- COL22A1 | c.219C>A p.D73E | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV100280317; called by muse, mutect2
- COL2A1 | c.2809C>T p.P937S | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as rs1440896814, COSV100477284; called by muse, mutect2, varscan2
- COL3A1 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100482776, COSV100483617; called by muse, mutect2, varscan2
- COL4A2 | c.2040T>C p.G680= | Splice Region (SNP) | VAF 27/96 reads (28%) | catalogued as COSV100847458; called by muse, mutect2, varscan2
- COL4A3 | c.908G>A p.G303D | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101170506; called by muse, mutect2, varscan2
- COL4A3 | c.2675G>A p.G892E | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101170507; called by muse, mutect2, varscan2
- COL4A4 | c.4225G>A p.G1409R | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771160320, COSV100307540; called by muse, mutect2, varscan2
- COL4A4 | c.3611G>A p.G1204E | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61631419; called by muse, mutect2, varscan2
- COL4A4 | c.1948C>T p.P650S | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.864); catalogued as rs1289625084, COSV100306237, COSV100307541; called by muse, mutect2, varscan2
- COL4A4 | c.1625G>A p.G542E | Missense Mutation (SNP) | VAF 66/131 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61632436; called by muse, mutect2, varscan2
- COL5A1 | c.3521G>A p.G1174E | Missense Mutation (SNP) | VAF 24/25 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100880446; called by muse, mutect2, varscan2
- COL6A5 | c.6070G>A p.G2024S (on ENST00000312481; = p.G2020S on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs750613367, COSV99594302; called by muse, mutect2, varscan2
- COL8A1 | c.1708C>T p.P570S | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.71); PolyPhen benign (0.013); catalogued as COSV99658284; called by muse, mutect2, varscan2
- COL9A1 | c.2042C>T p.S681F | Missense Mutation (SNP) | VAF 59/74 reads (80%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV100295404; called by muse, mutect2, varscan2
- COPS2 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 114/193 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV100157367; called by muse, mutect2, varscan2
- CPA3 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV56047592, COSV99936412; called by muse, mutect2, varscan2
- CPAMD8 | c.1255G>A p.D419N (on ENST00000651564; = p.D372N on NM_015692.5) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370768920, COSV52231899, COSV99359178; called by muse, mutect2, varscan2
- CPE | c.672G>A p.K224= | Splice Region (SNP) | VAF 23/44 reads (52%) | catalogued as rs1365729419, COSV101291679; called by muse, mutect2, varscan2
- CPED1 | c.2349G>A p.M783I | Missense Mutation (SNP) | VAF 58/135 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs940240594, COSV100121362; called by muse, mutect2, varscan2
- CPLANE2 | c.421T>C p.F141L | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT tolerated (0.16); PolyPhen benign (0.049); catalogued as COSV100983284; called by muse, mutect2, varscan2
- CPO | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 78/160 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.808); catalogued as rs771644753, COSV55939003; called by muse, mutect2, varscan2
- CPT1A | c.2168C>T p.S723L | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV99681531; called by muse, mutect2, varscan2
- CPXM2 | c.1786G>A p.D596N | Missense Mutation (SNP) | VAF 64/121 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs944271451, COSV53860832; called by muse, mutect2, varscan2
- CPXM2 | c.725G>A p.G242E | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.132); catalogued as COSV99583130; called by muse, mutect2, varscan2
- CR2 | c.1616C>T p.T539I | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV100889695; called by muse, mutect2, varscan2
- CRB1 | c.2242C>T p.P748S | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.179); catalogued as COSV100958054; called by muse, mutect2, varscan2
- CRHR2 | c.1090G>A p.G364R | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.638); catalogued as rs138130545; called by muse, mutect2, varscan2
- CROCC | c.1507C>T p.R503* | Nonsense Mutation (SNP) | VAF 6/9 reads (67%) | catalogued as rs1367026070, COSV65011946; called by muse, mutect2, varscan2
- CRP | c.540G>A p.W180* | Nonsense Mutation (SNP) | VAF 66/292 reads (23%) | catalogued as rs1365253097, COSV99660714; called by muse, mutect2
- CRTC2 | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100339301; called by muse, varscan2
- CRYBG1 | c.2261C>T p.T754I | Missense Mutation (SNP) | VAF 32/35 reads (91%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.007); catalogued as rs1333551472, COSV100954602; called by muse, mutect2, varscan2
- CRYBG1 | c.5716-1G>A p.X1906_splice | Splice Site (SNP) | VAF 10/17 reads (59%) | catalogued as rs1190705581; called by muse, mutect2
- CSF1 | c.675C>G p.D225E | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.968); catalogued as COSV100294807; called by muse, mutect2, varscan2
- CSF2RB | c.1582G>A p.G528R | Missense Mutation (SNP) | VAF 37/37 reads (100%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV99453493, COSV99454315; called by muse, mutect2, varscan2
- CSMD2 | c.4765G>A p.E1589K | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.98); PolyPhen benign (0.007); catalogued as rs749349455, COSV53914620; called by muse, mutect2, varscan2
- CSMD3 | c.4273A>G p.R1425G (on ENST00000297405 / NM_001363185.1; = p.R1321G on NM_052900.3) | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); catalogued as COSV99844751; called by muse, mutect2, varscan2
- CSMD3 | c.2050G>A p.D684N (on ENST00000297405 / NM_001363185.1; = p.D580N on NM_052900.3) | Missense Mutation (SNP) | VAF 78/191 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); catalogued as rs1415943509, COSV99844755; called by muse, mutect2, varscan2
- CSMD3 | c.1085G>A p.R362K | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV99033609; called by muse, mutect2, varscan2
- CSMD3 | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV52164534; called by muse, mutect2, varscan2
- CSMD3 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as COSV52327027; called by muse, mutect2, varscan2
- CSTA | c.107G>A p.G36E | Missense Mutation (SNP) | VAF 53/114 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99138696; called by muse, mutect2, varscan2
- CTNNBL1 | c.1534C>T p.R512C | Missense Mutation (SNP) | VAF 42/161 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs763375470, COSV63743440; called by muse, mutect2, varscan2
- CTSO | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 61/117 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as COSV101467881; called by muse, mutect2, varscan2
- CUBN | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.313); catalogued as COSV100912010, COSV100913379; called by muse, mutect2, varscan2
- CUL9 | c.2289G>C p.E763D | Missense Mutation (SNP) | VAF 186/321 reads (58%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV99335909; called by muse, mutect2, varscan2
- CUZD1 | c.662A>G p.N221S | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV100158953; called by muse, mutect2, varscan2
- CWC27 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV101126572; called by muse, mutect2, varscan2
- CXorf58 | c.31G>A p.G11S | Missense Mutation (SNP) | VAF 55/60 reads (92%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.026); catalogued as rs1468131181, COSV101003067; called by muse, mutect2, varscan2
- CXorf66 | c.773C>T p.S258F | Missense Mutation (SNP) | VAF 113/118 reads (96%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as rs1230564375, COSV100983822; called by muse, mutect2, varscan2
- CYP20A1 | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV100619123; called by muse, mutect2, varscan2
- CYP27C1 | c.1042A>G p.N348D | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100079994; called by muse, mutect2, varscan2
- CYP2C18 | c.1049C>T p.A350V | Missense Mutation (SNP) | VAF 81/141 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs771734535, COSV99608865; called by muse, mutect2, varscan2
- CYP2C19 | c.1169C>T p.S390F | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.845); catalogued as rs1196078753, COSV64907829; called by muse, mutect2, varscan2
- CYP2C9 | c.1169C>T p.S390F | Missense Mutation (SNP) | VAF 59/124 reads (48%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.473); catalogued as rs757323014, COSV53249002, COSV99583040; called by muse, mutect2, varscan2
- CYP2F1 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as rs1428404368, COSV58529050; called by muse, mutect2, varscan2
- CYP3A7 | c.1356G>A p.M452I | Missense Mutation (SNP) | VAF 89/206 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as COSV100312743; called by muse, mutect2, varscan2
- CYP3A7 | c.565T>A p.F189I | Missense Mutation (SNP) | VAF 64/144 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as COSV100312841; called by muse, mutect2, varscan2
- CYP4A11 | c.1066G>A p.G356S | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs369208625; called by muse, mutect2, varscan2
- CYP4B1 | c.1169C>T p.P390L | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV54726653, COSV99597413; called by muse, mutect2, varscan2
- CYP4F2 | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 74/169 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.651); catalogued as COSV99171124; called by muse, varscan2
- CYP8B1 | c.1132C>T p.H378Y | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV100296265; called by muse, mutect2, varscan2
- CYTH1 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 55/121 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV100739401; called by muse, mutect2, varscan2
- DACH2 | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 23/25 reads (92%) | SIFT tolerated (0.99); PolyPhen benign (0.018); catalogued as rs754076988, COSV100913758, COSV64176646; called by muse, mutect2, varscan2
- DACH2 | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 38/41 reads (93%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as rs1569485378, COSV64183018; called by muse, mutect2, varscan2
- DAG1 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs975742346, COSV100444621; called by muse, mutect2, varscan2
- DAP3 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV100546639; called by muse, mutect2, varscan2
- DCAF8 | c.578C>T p.T193I | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV100470739; called by muse, mutect2, varscan2
- DCC | c.3062G>A p.R1021Q | Missense Mutation (SNP) | VAF 61/117 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as rs370927048; called by muse, mutect2, varscan2
- DCC | c.3754C>T p.P1252S | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as COSV71428029; called by muse, mutect2, varscan2
- DCLK3 | c.663G>A p.M221I | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs752682808, COSV101374077; called by muse, mutect2, varscan2
- DCLRE1A | c.2479C>T p.L827F | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV100800465; called by muse, mutect2, varscan2
- DDX4 | c.1124G>A p.R375Q | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61756546; called by muse, mutect2, varscan2
- DENND2C | c.2168C>T p.T723I (on ENST00000393274 / NM_001256404.2; = p.T666I on NM_198459.4) | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67919918; called by muse, mutect2, varscan2
- DGCR2 | c.1390C>T p.P464S | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs773558627, COSV99593909; called by muse, mutect2, varscan2
- DGKB | c.201G>A p.M67I | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.254); catalogued as rs1180944970, COSV99342603; called by muse, mutect2, varscan2
- DGKE | c.1204C>T p.L402F | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.65); PolyPhen benign (0.014); catalogued as COSV99401160; called by muse, mutect2, varscan2
- DHCR24 | c.818C>T p.S273F | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV64874751; called by muse, mutect2, varscan2
- DIABLO | c.268C>T p.L90F (on ENST00000443649 / NM_001278303.1; = p.L163F on NM_019887.6) | Missense Mutation (SNP) | VAF 79/87 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99928341; called by muse, mutect2, varscan2
- DIAPH1 | c.997C>T p.H333Y | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53885122; called by muse, mutect2, varscan2
- DIP2B | c.3838C>T p.R1280W | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99999206; called by muse, mutect2, varscan2
- DLG2 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 65/165 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.025); catalogued as rs374177340, COSV101074026; called by muse, mutect2, varscan2
- DLGAP2 | c.2587C>T p.P863S | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.997); catalogued as COSV70098363; called by muse, mutect2, varscan2
- DLX4 | c.445C>T p.Q149* (on ENST00000240306 / NM_138281.3; = p.Q77* on NM_001934.3) | Nonsense Mutation (SNP) | VAF 20/39 reads (51%) | catalogued as rs1285248412, COSV99537730; called by muse, mutect2, varscan2
- DMKN | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as rs754959997, COSV100303901; called by muse, mutect2, varscan2
- DNAAF5 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV99860205; called by muse, mutect2, varscan2
- DNAAF6 | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 25/27 reads (93%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.239); catalogued as COSV100314575; called by muse, mutect2, varscan2
- DNAH1 | c.10816C>T p.P3606S | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1266594017, COSV101326847; called by muse, mutect2, varscan2
- DNAH11 | c.3487G>A p.E1163K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.017); catalogued as COSV100180400; called by muse, mutect2, varscan2
- DNAH11 | c.3488A>T p.E1163V | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV100180402; called by muse, mutect2, varscan2
- DNAH11 | c.10720G>A p.E3574K | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV100180403; called by muse, mutect2, varscan2
- DNAH17 | c.9547A>C p.S3183R | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV101103213; called by muse, mutect2, varscan2
- DNAH17 | c.5515C>T p.L1839F | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1456868987, COSV101103216, COSV67752403; called by muse, mutect2, varscan2
- DNAH3 | c.10159G>A p.E3387K | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV54504699, COSV54505840; called by muse, mutect2, varscan2
- DNAH3 | c.5642A>G p.E1881G | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV99770011; called by muse, mutect2, varscan2
- DNAH5 | c.6796G>A p.A2266T | Missense Mutation (SNP) | VAF 33/52 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.175); catalogued as rs1023849945, COSV99453148; called by muse, mutect2, varscan2
- DNAH5 | c.3910T>C p.Y1304H | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.25); catalogued as COSV99453151; called by muse, varscan2
- DNAH7 | c.7096G>A p.E2366K | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs145374108, COSV56779310; called by muse, mutect2, varscan2
- DNAH8 | c.3112G>A p.E1038K | Missense Mutation (SNP) | VAF 110/165 reads (67%) | SIFT tolerated (0.51); PolyPhen benign (0.23); catalogued as COSV100546860, COSV59469132; called by muse, mutect2, varscan2
- DNAH8 | c.9535C>T p.P3179S | Missense Mutation (SNP) | VAF 70/115 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs758710947, COSV100546861; called by muse, mutect2, varscan2
- DNAH8 | c.10261C>T p.P3421S | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs953211968, COSV59447877; called by muse, mutect2, varscan2
- DNAH9 | c.2900C>T p.S967F | Missense Mutation (SNP) | VAF 53/61 reads (87%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as COSV52335986; called by muse, mutect2, varscan2
- DNM3 | c.175C>T p.R59* | Nonsense Mutation (SNP) | VAF 5/25 reads (20%) | catalogued as rs745812518, COSV100798594, COSV62454976; called by muse, mutect2, varscan2
- DOCK4 | c.1441C>T p.R481W | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs764783981, COSV70326490; called by muse, mutect2, varscan2
- DOCK9 | c.2813C>T p.S938F (on ENST00000376460 / NM_001366676.2; = p.S939F on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.69); PolyPhen benign (0.104); catalogued as COSV100239924; called by muse, mutect2, varscan2
- DOK1 | c.1261C>T p.L421F | Missense Mutation (SNP) | VAF 66/147 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as COSV99284175; called by muse, mutect2, varscan2
- DOK5 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs765612921, COSV52817152; called by muse, mutect2, varscan2
- DOK7 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.028); catalogued as rs1359635065, COSV100403535; ClinVar: uncertain significance; called by muse, varscan2
- DOP1B | c.3572C>T p.S1191L | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201842098, COSV67692421; called by muse, mutect2, varscan2
- DPP4 | c.1619A>T p.Y540F | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV100859018; called by muse, mutect2, varscan2
- DPP4 | c.1276C>T p.P426S | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1209315967, COSV100859019; called by muse, mutect2, varscan2
- DPP6 | c.253G>A p.G85R (on ENST00000377770 / NM_001364500.2; = p.G23R on NM_001936.5) | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100122333, COSV100127589; called by muse, mutect2, varscan2
- DPYD | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV100928369; called by muse, mutect2, varscan2
- DPYSL4 | c.863C>T p.S288L | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV100634024; called by muse, mutect2, varscan2
- DRC1 | c.1865C>T p.P622L | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99718698; called by muse, mutect2, varscan2
- DRD3 | c.718C>T p.Q240* | Nonsense Mutation (SNP) | VAF 28/86 reads (33%) | catalogued as COSV99879556, COSV99879648; called by muse, mutect2, varscan2
- DRD5 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV100431992, COSV58578573; called by muse, mutect2, varscan2
- DSC1 | c.2341G>A p.E781K | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV99938139; called by muse, mutect2, varscan2
- DSCAM | c.4438G>A p.E1480K | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.308); catalogued as COSV68022585; called by muse, mutect2, varscan2
- DSG4 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV57388185; called by muse, mutect2, varscan2
- DSN1 | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 75/130 reads (58%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as COSV101041098; called by muse, mutect2, varscan2
- DSP | c.4373G>A p.R1458Q | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.111); catalogued as rs370063434, COSV65791413; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSPP | c.91T>A p.S31T | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.736); catalogued as COSV99217837; called by muse, mutect2, varscan2
- DYNC1I1 | c.1708A>G p.T570A | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs762080244, COSV100269059; called by muse, mutect2
- DYRK4 | c.407G>A p.R136K | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as COSV99157723; called by muse, mutect2, varscan2
- DYSF | c.4638+1G>A p.X1546_splice | Splice Site (SNP) | VAF 113/219 reads (52%) | catalogued as rs754039882, COSV99249953; called by muse, mutect2, varscan2
- E2F3 | c.223C>T p.Q75* | Nonsense Mutation (SNP) | VAF 13/54 reads (24%) | catalogued as rs1561842818, COSV100686199; called by muse, mutect2, varscan2
- EBF2 | c.1181G>A p.R394Q | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs369154726; called by muse, mutect2, varscan2
- EFHB | c.2206C>T p.R736C | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs758950065, COSV99860127; called by muse, mutect2, varscan2
- EFHC1 | c.1261C>T p.R421C | Missense Mutation (SNP) | VAF 103/178 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as rs144389178; called by muse, mutect2, varscan2
- EGFLAM | c.2911G>A p.E971K (on ENST00000354891 / NM_001205301.2; = p.E963K on NM_152403.4) | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.964); catalogued as COSV59294308; called by muse, mutect2, varscan2
- EIF3K | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV99943164; called by muse, mutect2, varscan2
- EIF4A1 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 85/103 reads (83%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); catalogued as rs779627306, COSV99549208; called by muse, mutect2, varscan2
- ELAPOR2 | c.947C>T p.S316F (on ENST00000450689 / NM_001142749.3; = p.S149F on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/105 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99789271; called by muse, mutect2, varscan2
- ELAVL2 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 82/91 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99806971; called by muse, mutect2, varscan2
- ELOVL2 | c.64C>G p.R22G | Missense Mutation (SNP) | VAF 73/126 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV100676031; called by muse, mutect2, varscan2
- EML2 | c.1694-1G>A p.X565_splice | Splice Site (SNP) | VAF 15/41 reads (37%) | catalogued as rs751787095, COSV55598057; called by muse, mutect2, varscan2
- EMP2 | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as rs764490312, COSV100852866; called by muse, mutect2, varscan2
- EMSY | c.715C>A p.P239T | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.996); catalogued as COSV100595985; called by muse, mutect2, varscan2
- ENDOV | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100108631; called by muse, mutect2, varscan2
- ENOX1 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 53/196 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.198); catalogued as rs370105336; called by muse, mutect2, varscan2
- ENPP7 | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs782599171, COSV100093647; called by muse, mutect2, varscan2
- ENTPD1 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT tolerated (0.64); PolyPhen benign (0.014); catalogued as COSV100967703; called by muse, mutect2, varscan2
- EPB41L1 | c.1660G>A p.A554T | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT tolerated (0.14); PolyPhen benign (0.344); catalogued as COSV99151461; called by muse, mutect2, varscan2
- EPHA6 | c.1822C>T p.H608Y | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV67572863; called by muse, mutect2, varscan2
- EPHA7 | c.2111G>A p.G704E | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV100994002, COSV100994207; called by muse, mutect2, varscan2
- EPHX4 | c.415C>T p.R139* | Nonsense Mutation (SNP) | VAF 17/48 reads (35%) | catalogued as rs201340952, COSV64889460; called by muse, mutect2, varscan2
- EPPK1 | c.6721G>A p.E2241K | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV101599940; called by muse, mutect2
- EPYC | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 47/51 reads (92%) | SIFT tolerated (0.31); PolyPhen benign (0.037); catalogued as rs770231424, COSV53802276; called by muse, mutect2, varscan2
- ERCC2 | c.419C>T p.S140F | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV99676479; called by muse, mutect2, varscan2
- ERCC3 | c.365C>T p.S122F | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99573621; called by muse, mutect2, varscan2
- ERG | c.1336C>T p.P446S (on ENST00000398919 / NM_001243428.1; = p.P422S on NM_004449.4) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.099); catalogued as COSV99902606; called by muse, mutect2, varscan2
- ERICH3 | c.1436G>A p.G479E | Missense Mutation (SNP) | VAF 81/165 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.168); catalogued as COSV58602480; called by muse, mutect2, varscan2
- ESPL1 | c.1076C>T p.A359V | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as COSV99229683; called by muse, varscan2
- F11 | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99251761; called by muse, mutect2, varscan2
- F13A1 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV99343753; called by muse, mutect2, varscan2
- F13B | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 63/92 reads (68%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.936); catalogued as rs1294347544, COSV66372739; called by muse, mutect2
- F2 | c.578T>A p.V193E | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.098); catalogued as COSV100319656; called by muse, mutect2, varscan2
- F2RL2 | c.1099C>T p.H367Y | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.25); catalogued as COSV99167890; called by muse, mutect2, varscan2
- FAHD2B | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99738231; called by muse, mutect2, varscan2
- FAM122B | c.118C>T p.Q40* | Nonsense Mutation (SNP) | VAF 19/20 reads (95%) | catalogued as COSV99980476; called by muse, mutect2, varscan2
- FAM133A | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.295); catalogued as COSV59075224; called by muse, mutect2, varscan2
- FAM170A | c.229C>T p.R77* | Nonsense Mutation (SNP) | VAF 32/55 reads (58%) | catalogued as rs745479291, COSV58924182; called by muse, mutect2, varscan2
- FAM171A1 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1454149720, COSV100968479; called by muse, mutect2, varscan2
- FAM171A1 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100968480; called by muse, mutect2, varscan2
- FAM193A | c.1378C>T p.P460S | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV100219506; called by muse, mutect2, varscan2
- FAM209B | c.218T>C p.L73P | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100991014; called by muse, mutect2, varscan2
- FAM214A | c.1050G>C p.Q350H | Missense Mutation (SNP) | VAF 39/55 reads (71%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV99958424; called by muse, mutect2, varscan2
- FAM216B | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV100573087, COSV99047556; called by muse, mutect2, varscan2
- FAM221A | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs771966204, COSV100794374; called by muse, mutect2, varscan2
- FAM83B | c.1391G>A p.R464Q | Missense Mutation (SNP) | VAF 69/110 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs147022305; called by muse, mutect2, varscan2
- FAM90A1 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 55/263 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.14); catalogued as rs777961138, COSV56710265; called by muse, mutect2, varscan2
- FAP | c.2096G>A p.G699E | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99502395; called by muse, mutect2, varscan2
- FAT1 | c.7675C>T p.P2559S | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.174); catalogued as COSV101499571, COSV71675333; called by muse, mutect2, varscan2
- FAT3 | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs771773390, COSV53074488; called by muse, mutect2, varscan2
- FAT3 | c.2884G>A p.D962N | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774871868, COSV53101177, COSV53151158; called by muse, mutect2, varscan2
- FAT4 | c.4027G>A p.D1343N | Missense Mutation (SNP) | VAF 67/145 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1390670394, COSV67881115; called by muse, mutect2, varscan2
- FAT4 | c.7468G>A p.V2490I | Missense Mutation (SNP) | VAF 67/146 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.197); catalogued as COSV100629806; called by muse, mutect2, varscan2
- FAT4 | c.12411G>A p.M4137I | Missense Mutation (SNP) | VAF 74/172 reads (43%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.758); catalogued as COSV100627166; called by muse, mutect2, varscan2
- FBH1 | c.25C>T p.L9F (on ENST00000362091 / NM_178150.3; = p.L60F on NM_032807.4) | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as COSV100758906; called by muse, mutect2, varscan2
- FBXL13 | c.1313G>A p.G438E | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.39); PolyPhen benign (0.04); catalogued as COSV100502009; called by muse, mutect2, varscan2
- FBXO3 | c.866C>T p.S289F | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV99682304; called by muse, mutect2, varscan2
- FBXO30 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 40/46 reads (87%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.814); catalogued as COSV99395383; called by muse, mutect2, varscan2
- FBXW7 | c.1762G>A p.E588K (on ENST00000281708 / NM_001349798.2; = p.E508K on NM_018315.5) | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as rs1224653860, COSV55931879, COSV99660107; called by muse, mutect2, varscan2
- FCGBP | c.4512C>A p.N1504K | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); catalogued as COSV99663709; called by muse, mutect2, varscan2
- FCRL6 | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT tolerated (0.85); PolyPhen benign (0.231); catalogued as COSV100220325, COSV58942703; called by muse, mutect2, varscan2
- FEM1C | c.682A>G p.N228D | Missense Mutation (SNP) | VAF 46/89 reads (52%) | SIFT tolerated (0.4); PolyPhen benign (0.318); catalogued as COSV99174410; called by muse, mutect2, varscan2
- FERMT1 | c.691C>T p.L231F | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.914); catalogued as COSV99451996; called by muse, mutect2, varscan2
- FGF13 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 57/62 reads (92%) | SIFT tolerated (0.15); PolyPhen benign (0.051); catalogued as rs1264974671, COSV59542497; called by muse, mutect2, varscan2
- FH | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as rs368849989, COSV63818443; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FKBP5 | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 92/146 reads (63%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs374759584; called by muse, mutect2, varscan2
- FKBP8 | c.430G>C p.V144L | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.102); catalogued as COSV99724242; called by muse, mutect2, varscan2
- FLG | c.11779G>A p.E3927K | Missense Mutation (SNP) | VAF 76/172 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.341); catalogued as rs1557869612, COSV64240624; called by muse, mutect2, varscan2
- FLG | c.5032G>A p.G1678R | Missense Mutation (SNP) | VAF 164/831 reads (20%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.999); catalogued as COSV64242375; called by muse, mutect2, varscan2
- FLG | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 100/226 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV64237841, COSV64239483; called by muse, mutect2, varscan2
- FLNB | c.4627G>A p.D1543N | Missense Mutation (SNP) | VAF 56/121 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV55878149; called by muse, mutect2, varscan2
- FMN2 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.073); catalogued as COSV100146867, COSV60447753; called by muse, mutect2, varscan2
- FMN2 | c.1718C>A p.P573H | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100146868; called by muse, mutect2, varscan2
- FMN2 | c.2747C>T p.P916L | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.259); catalogued as rs771688332, COSV60463233; called by muse, mutect2, varscan2
- FMNL1 | c.2218G>A p.D740N | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.956); catalogued as rs753325510, COSV100056853; called by muse, mutect2, varscan2
- FMO1 | c.737C>T p.S246F | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.011); catalogued as rs760400584, COSV61444971; called by muse, mutect2, varscan2
- FN1 | c.1145G>A p.G382E | Missense Mutation (SNP) | VAF 63/124 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100118010, COSV60564215; called by muse, mutect2, varscan2
- FOS | c.939G>A p.M313I | Missense Mutation (SNP) | VAF 39/67 reads (58%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.003); catalogued as rs1178154622, COSV100338557; called by muse, mutect2, varscan2
- FOXJ3 | c.1817C>T p.S606F | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0.057); catalogued as COSV100692142; called by muse, mutect2, varscan2
- FRAS1 | c.6503G>A p.G2168E | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs267600270, COSV53626842; called by muse, mutect2, varscan2
- FRAS1 | c.6970G>A p.E2324K | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV53603877, COSV99355189; called by muse, mutect2, varscan2
- FRMPD2 | c.2255G>A p.S752N | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100564107; called by muse, mutect2, varscan2
- FRMPD4 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 31/34 reads (91%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.588); catalogued as rs1399275095, COSV66211481; called by muse, mutect2, varscan2
- FSIP2 | c.17308G>A p.D5770N | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs1479991993, COSV100555547; called by muse, mutect2, varscan2
- FSIP2 | c.19867G>A p.D6623N | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100556075; called by muse, mutect2, varscan2
- FSTL5 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as rs1026863704, COSV60179915, COSV60188557; called by muse, mutect2, varscan2
- FSTL5 | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.628); catalogued as rs765043827, COSV100059998; called by muse, mutect2, varscan2
- GAA | c.1796C>T p.S599F | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM081626, CM1515310, COSV100163470; called by muse, mutect2, varscan2
- GAB3 | c.1631C>T p.A544V | Missense Mutation (SNP) | VAF 101/108 reads (94%) | SIFT tolerated (0.08); PolyPhen benign (0.177); catalogued as COSV100850683; called by muse, mutect2, varscan2
- GABPB2 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.166); catalogued as rs1433148865, COSV64460961; called by muse, mutect2, varscan2
- GABRA1 | c.392G>A p.G131E | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749642686, COSV99196209; called by muse, mutect2, varscan2
- GABRA1 | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV50116075, COSV99196161; called by muse, mutect2, varscan2
- GABRG1 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.006); catalogued as COSV99778594; called by muse, mutect2, varscan2
- GALE | c.643-1G>A p.X215_splice | Splice Site (SNP) | VAF 9/16 reads (56%) | catalogued as COSV99354075; called by muse, mutect2, varscan2
- GALK2 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100509178; called by muse, mutect2, varscan2
- GALNT16 | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); catalogued as COSV61884946; called by muse, mutect2, varscan2
- GALNT5 | c.2236G>A p.V746M | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV99375511; called by muse, mutect2, varscan2
- GHDC | c.956C>T p.P319L | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.028); catalogued as COSV100054909; called by muse, mutect2, varscan2
- GIMAP1 | c.319C>T p.L107F | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs371565531, COSV100212271, COSV56187671; called by muse, mutect2, varscan2
- GIMAP7 | c.167G>A p.G56E | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.666); catalogued as rs769439572, COSV100543752; called by muse, mutect2, varscan2
- GIMAP7 | c.635G>A p.R212K | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs867128850, COSV100543754; called by muse, mutect2, varscan2
- GJD2 | c.374G>A p.G125E | Missense Mutation (SNP) | VAF 103/155 reads (66%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51747502; called by muse, mutect2, varscan2
- GKN2 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 61/123 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100187922; called by muse, mutect2, varscan2
- GLI2 | c.2236G>A p.G746R (on ENST00000361492 / NM_001374353.1; = p.G763R on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV58053248; called by muse, mutect2, varscan2
- GLT8D2 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 25/30 reads (83%) | SIFT tolerated (0.12); PolyPhen benign (0.131); catalogued as rs751805819, COSV62561628; called by muse, mutect2, varscan2
- GLYAT | c.275C>T p.S92L | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.037); catalogued as rs1313996886, COSV99557522; called by muse, mutect2, varscan2
- GLYATL1 | c.824G>A p.R275K (on ENST00000317391 / NM_001354699.1; = p.R306K on NM_080661.4) | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as COSV100265513, COSV55607504; called by muse, mutect2, varscan2
- GMPS | c.62A>T p.H21L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99903333; called by muse, mutect2, varscan2
- GOLGA6B | c.1679G>A p.G560E | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.091); catalogued as COSV101406940; called by mutect2, varscan2
- GOLM2 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100248027; called by muse, mutect2, varscan2
- GPATCH2 | c.483G>T p.R161S | Missense Mutation (SNP) | VAF 118/178 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100861421; called by muse, mutect2, varscan2
- GPC6 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1441732321, COSV100989842; called by muse, mutect2, varscan2
- GPLD1 | c.1889C>T p.P630L | Missense Mutation (SNP) | VAF 88/246 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100015538; called by muse, mutect2, varscan2
- GPR153 | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100928594; called by muse, mutect2, varscan2
- GPR158 | c.3128C>T p.S1043F | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1374104989, COSV66264976, COSV66273219; called by muse, mutect2, varscan2
- GPR179 | c.3673G>A p.E1225K (on ENST00000621958; = p.E1224K on NM_001004334.4) | Missense Mutation (SNP) | VAF 69/139 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.426); catalogued as rs748125701; called by muse, mutect2, varscan2
- GPR180 | c.1138A>C p.I380L | Missense Mutation (SNP) | VAF 103/166 reads (62%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV100979095; called by muse, mutect2, varscan2
- GPR50 | c.290G>A p.S97N | Missense Mutation (SNP) | VAF 116/123 reads (94%) | SIFT tolerated (0.09); PolyPhen benign (0.246); catalogued as COSV99506504; called by muse, mutect2, varscan2
- GPX3 | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100161701; called by muse, mutect2, varscan2
- GREB1 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 47/88 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.085); catalogued as rs1340116167, COSV99303609; called by muse, mutect2, varscan2
- GREB1 | c.1288C>T p.Q430* | Nonsense Mutation (SNP) | VAF 22/77 reads (29%) | catalogued as COSV99303612; called by muse, mutect2, varscan2
- GRIA4 | c.1603G>A p.G535R | Missense Mutation (SNP) | VAF 75/173 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV99233908; called by muse, mutect2, varscan2
- GRIA4 | c.2401G>A p.G801R | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.367); catalogued as COSV99233911; called by muse, mutect2, varscan2
- GRID1 | c.2888C>T p.S963F | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.085); catalogued as rs375508008; called by muse, mutect2, varscan2
- GRIK1 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs546213634, COSV58718557; called by muse, mutect2, varscan2
- GRIN2A | c.4340C>T p.S1447F | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58027331; called by muse, mutect2, varscan2
- GRIN2A | c.3457G>A p.D1153N | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as rs267604687, COSV58027768; called by muse, mutect2, varscan2
- GRIN2A | c.1909T>C p.F637L | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100410780; called by muse, mutect2, varscan2
- GRIN2B | c.2086C>T p.R696C | Missense Mutation (SNP) | VAF 80/130 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV74207423; called by muse, mutect2, varscan2
- GRIN2B | c.1481G>A p.W494* | Nonsense Mutation (SNP) | VAF 161/265 reads (61%) | catalogued as rs1555112139, COSV101663159; called by muse, mutect2, varscan2
- GRIN2D | c.2168G>A p.R723H | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99616856; called by muse, varscan2
- GRIN2D | c.2179C>T p.P727S | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); catalogued as COSV99616859; called by muse, varscan2
- GRIP2 | c.2890G>A p.E964K (on ENST00000619221; = p.E867K on NM_001080423.4) | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as rs1197661195, COSV99817596; called by muse, mutect2, varscan2
- GRM8 | c.958C>T p.Q320* | Nonsense Mutation (SNP) | VAF 43/124 reads (35%) | catalogued as COSV58835482; called by muse, mutect2, varscan2
- GSX2 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as rs1170284552, COSV100482612; called by muse, mutect2, varscan2
- GUCY2C | c.1415C>T p.P472L | Missense Mutation (SNP) | VAF 103/166 reads (62%) | SIFT tolerated (0.07); PolyPhen benign (0.28); catalogued as rs760181030, COSV99664060; called by muse, mutect2, varscan2
- GULP1 | c.190G>A p.G64S | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs1233908700, COSV100771068; called by muse, mutect2, varscan2
- GZMA | c.610G>A p.G204R | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.5); catalogued as COSV99697288; called by muse, mutect2, varscan2
- HAO2 | c.22G>A p.D8N | Missense Mutation (SNP) | VAF 69/150 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1421632844, COSV100378237; called by muse, mutect2, varscan2
- HCN1 | c.2453C>T p.P818L | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.593); catalogued as COSV100301834; called by muse, mutect2, varscan2
- HDAC9 | c.2973G>A p.M991I | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1354211036, COSV101287086; called by muse, mutect2
- HEATR6 | c.3074C>T p.S1025F | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV99482563; called by muse, mutect2, varscan2
- HELB | c.1855C>T p.L619F | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56073517, COSV56076479; called by muse, mutect2, varscan2
- HELQ | c.2500G>A p.G834R | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99788052; called by muse, mutect2, varscan2
- HELZ2 | c.3850C>T p.R1284W (on ENST00000467148 / NM_001037335.2; = p.R715W on NM_033405.3) | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as rs755141131, COSV101427602; called by muse, mutect2, varscan2
- HERC1 | c.9426T>C p.G3142= | Splice Region (SNP) | VAF 21/43 reads (49%) | catalogued as rs1364885843, COSV101496835, COSV71249890; called by muse, mutect2, varscan2
- HERC2 | c.2365C>T p.P789S | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.508); catalogued as COSV55349970; called by muse, mutect2, varscan2
- HGF | c.113C>A p.T38K | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.088); catalogued as COSV99738196; called by muse, mutect2, varscan2
- HGF | c.112A>T p.T38S | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.64); PolyPhen benign (0.026); catalogued as COSV99738200; called by muse, mutect2, varscan2
- HGFAC | c.1666G>A p.E556K | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV101237781; called by muse, mutect2, varscan2
- HHIPL2 | c.1540C>T p.L514F | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100597045; called by muse, mutect2, varscan2
- HHLA2 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV100755519; called by muse, mutect2, varscan2
- HHLA2 | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs776405465, COSV100755520; called by muse, mutect2, varscan2
- HIC2 | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV101335622; called by muse, mutect2, varscan2
- HIPK3 | c.2419C>T p.P807S | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.186); catalogued as COSV100306008; called by muse, mutect2, varscan2
- HMCN1 | c.2751T>A p.N917K | Missense Mutation (SNP) | VAF 165/250 reads (66%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.951); catalogued as COSV99634377; called by muse, mutect2, varscan2
- HMGB4 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT tolerated (0.05); PolyPhen benign (0.046); catalogued as COSV99594216; called by muse, mutect2, varscan2
- HNF4A | c.938C>T p.S313F | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV100291687; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.134G>T p.G45V (on ENST00000354667 / NM_031243.3; = p.G33V on NM_002137.4) | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100522998; called by muse, mutect2, varscan2
- HORMAD1 | c.1040G>A p.G347E | Missense Mutation (SNP) | VAF 56/88 reads (64%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as rs1166641975, COSV55047262, COSV55047593; called by muse, mutect2, varscan2
- HOXC13 | c.965C>T p.S322L | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV54498348; called by muse, mutect2, varscan2
- HOXD4 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV100107006, COSV100107066; called by muse, mutect2, varscan2
- HPS6 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as rs750596834, COSV100154978; called by muse, mutect2, varscan2
- HS3ST2 | c.970C>T p.R324* | Nonsense Mutation (SNP) | VAF 92/185 reads (50%) | catalogued as COSV54470119; called by muse, mutect2, varscan2
- HS3ST3B1 | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1295879193, COSV62907483; called by muse, mutect2
- HTRA4 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 61/146 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as COSV100205905; called by muse, mutect2, varscan2
- HYDIN | c.2149G>A p.E717K | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs746665991, COSV99864792; called by muse, mutect2, varscan2
- HYDIN | c.1330C>T p.R444* | Nonsense Mutation (SNP) | VAF 21/59 reads (36%) | catalogued as rs755996140, COSV99864796; called by muse, mutect2, varscan2
- HYDIN | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1432669558, COSV99864805; called by muse, mutect2, varscan2
- IBSP | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.18); catalogued as COSV99883740; called by muse, mutect2, varscan2
- ICA1L | c.956G>A p.G319E | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as COSV100841871; called by muse, mutect2, varscan2
- IFNG | c.9T>A p.Y3* | Nonsense Mutation (SNP) | VAF 13/31 reads (42%) | catalogued as rs1358756680, COSV99971262; called by muse, mutect2, varscan2
- IGDCC3 | c.2047C>T p.P683S | Missense Mutation (SNP) | VAF 48/89 reads (54%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.054); catalogued as COSV60080224; called by muse, mutect2, varscan2
- IGFBP2 | c.922C>T p.L308F | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.59); catalogued as rs1394688213, COSV99288578; called by muse, mutect2, varscan2
- IGHV1-58 | c.223G>A p.G75S | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.341); catalogued as rs782336477; called by muse, mutect2, varscan2
- IGHV3-23 | c.263C>T p.T88I | Missense Mutation (SNP) | VAF 98/569 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.355); catalogued as rs1064092; called by muse, mutect2, varscan2
- IGHV4-4 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.463); catalogued as rs782543865; called by muse, mutect2, varscan2
- IGKV1-17 | c.260G>A p.S87N | Missense Mutation (SNP) | VAF 74/200 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs780717964; called by muse, mutect2, varscan2
- IGLV6-57 | c.165G>A p.W55* | Nonsense Mutation (SNP) | VAF 21/37 reads (57%) | catalogued as rs554241548, COSV66504225, COSV66504317, COSV66504350; called by muse, mutect2, varscan2
- IGSF22 | c.2470G>A p.E824K (on ENST00000319338; = p.E925K on NM_173588.4) | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.65); PolyPhen benign (0.055); catalogued as COSV99773846; called by muse, mutect2, varscan2
- IGSF9B | c.3320C>T p.S1107L | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs755766026, COSV100318262; called by muse, mutect2, varscan2
- IL10RA | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.494); catalogued as COSV99923232; called by muse, mutect2, varscan2
- IL18RAP | c.1447C>T p.P483S | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); catalogued as rs749538877, COSV99962321; called by muse, mutect2, varscan2
- IL1RL1 | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52120010; called by muse, mutect2, varscan2
- IL1RL2 | c.489G>A p.K163= | Splice Region (SNP) | VAF 21/47 reads (45%) | catalogued as COSV99961023; called by muse, mutect2, varscan2
- IL20 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV100894167, COSV65585292; called by muse, mutect2, varscan2
- IL37 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.061); catalogued as COSV54490568, COSV99636450; called by muse, mutect2, varscan2
- IL3RA | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.039); catalogued as COSV100452376; called by muse, mutect2, varscan2
- ILDR1 | c.464G>C p.G155A | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56551674, COSV99878863; called by muse, mutect2, varscan2
- IMPG2 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as COSV99516269; called by muse, mutect2, varscan2
- INCENP | c.2492C>T p.S831F (on ENST00000394818 / NM_001040694.2; = p.S827F on NM_020238.3) | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99611380; called by muse, mutect2, varscan2
- INHBA | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs564878978, COSV54222103; called by muse, mutect2, varscan2
- INO80 | c.2693C>T p.P898L | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV100732035; called by muse, mutect2, varscan2
- INPP5D | c.3269C>T p.S1090F (on ENST00000445964 / NM_001017915.3; = p.S1089F on NM_005541.5) | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs1270207920, COSV100856898; called by muse, mutect2, varscan2
- INTS12 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.141); catalogued as COSV100415912; called by muse, mutect2, varscan2
- IPO8 | c.483-1G>A p.X161_splice | Splice Site (SNP) | VAF 37/131 reads (28%) | catalogued as COSV99805608; called by muse, mutect2, varscan2
- IQCB1 | c.394-1G>A p.X132_splice | Splice Site (SNP) | VAF 7/31 reads (23%) | catalogued as rs768014052, COSV100182079; called by muse, mutect2
- IQGAP2 | c.1190C>T p.P397L | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.175); catalogued as rs1402040324, COSV99167889; called by muse, mutect2, varscan2
- ITGA10 | c.1406G>A p.G469E | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.677); catalogued as rs1553748479, COSV100995012; called by muse, mutect2, varscan2
- ITGA4 | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV99276725; called by muse, mutect2, varscan2
- ITGA8 | c.2309C>T p.P770L | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.784); catalogued as COSV100959605; called by muse, mutect2, varscan2
- ITGA8 | c.2053G>A p.E685K | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100959606; called by muse, varscan2
- ITGA8 | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.913); catalogued as COSV100959558, COSV65223898; called by muse, varscan2
- ITGA8 | c.586G>A p.G196S | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100959608; called by muse, mutect2, varscan2
- ITGAM | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.938); catalogued as rs199508009; called by muse, mutect2, varscan2
- ITGB4 | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52321836; called by muse, mutect2, varscan2
- ITIH5 | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99905531; called by muse, mutect2, varscan2
- ITPR2 | c.2440C>T p.H814Y | Missense Mutation (SNP) | VAF 80/136 reads (59%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV67274382; called by muse, mutect2, varscan2
- ITSN2 | c.1344+2T>C p.X448_splice | Splice Site (SNP) | VAF 21/46 reads (46%) | catalogued as COSV100744061; called by muse, mutect2, varscan2
- IWS1 | c.377G>A p.R126K | Missense Mutation (SNP) | VAF 97/207 reads (47%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.021); catalogued as COSV99767013, COSV99767490; called by muse, mutect2, varscan2
- JPH3 | c.923G>A p.G308E | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52468618; called by muse, mutect2, varscan2
- KALRN | c.6952G>A p.G2318R (on ENST00000360013 / NM_001024660.4; = p.G621R on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.498); catalogued as rs763247639, COSV52262755; called by muse, mutect2, varscan2
- KANSL1L | c.209C>T p.S70F | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201038662, COSV55990048; called by muse, mutect2, varscan2
- KAT6B | c.2980A>T p.N994Y | Missense Mutation (SNP) | VAF 52/97 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV99768856; called by muse, mutect2, varscan2
- KAT6B | c.3655C>T p.P1219S | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.026); catalogued as COSV99768118, COSV99768860; called by muse, mutect2, varscan2
- KATNAL2 | c.986G>A p.G329E (on ENST00000356157 / NM_001353899.1; = p.G257E on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55296186, COSV99797704; called by muse, mutect2, varscan2
- KCNH5 | c.2278C>T p.P760S | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.164); catalogued as COSV100527793; called by muse, mutect2, varscan2
- KCNH5 | c.1778G>A p.G593E | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100527795, COSV59768158; called by muse, mutect2, varscan2
- KCNH7 | c.1597C>T p.R533C | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99045936; called by muse, mutect2, varscan2
- KCNK5 | c.757C>T p.H253Y | Missense Mutation (SNP) | VAF 112/170 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as COSV100851919; called by muse, mutect2, varscan2
- KCNN1 | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.922); catalogued as rs1233681689, COSV55842743; called by muse, mutect2, varscan2
- KCNQ3 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs774311301, COSV66468995; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNT1 | c.982G>A p.E328K (on ENST00000488444; = p.E347K on NM_020822.3) | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs913411736, COSV99706509; called by muse, mutect2, varscan2
- KCNT2 | c.3223G>A p.D1075N | Missense Mutation (SNP) | VAF 57/285 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.081); catalogued as COSV99656137; called by muse, mutect2, varscan2
- KCNT2 | c.646G>A p.G216R | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1362891679, COSV99656141; called by muse, mutect2, varscan2
- KCNT2 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 90/133 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1452776560, COSV54065701; called by muse, mutect2, varscan2
- KCNV1 | c.815G>A p.R272K | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (1); PolyPhen possibly damaging (0.587); catalogued as COSV52085135, COSV99819377; called by muse, mutect2, varscan2
- KIAA0100 | c.5542A>C p.N1848H | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV101197389; called by muse, mutect2, varscan2
- KIAA0319 | c.2185C>T p.L729F | Missense Mutation (SNP) | VAF 63/196 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100985760; called by muse, mutect2, varscan2
- KIAA0408 | c.569A>G p.N190S | Missense Mutation (SNP) | VAF 37/43 reads (86%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as COSV100847033; called by muse, mutect2, varscan2
- KIAA0825 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs934109207, COSV56950262; called by muse, mutect2, varscan2
- KIAA1217 | c.3583G>A p.E1195K | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.879); catalogued as COSV56823260; called by muse, mutect2, varscan2
- KIF13B | c.1111C>T p.L371F | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101580787; called by muse, mutect2, varscan2
- KIF2C | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.677); catalogued as COSV100945840; called by muse, mutect2, varscan2
- KIR2DL1 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 57/119 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.31); catalogued as rs757819906, COSV52410516; called by muse, mutect2, varscan2
- KLHDC7A | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as rs1268353271, COSV101272841; called by muse, mutect2, varscan2
- KMT5C | c.695A>C p.H232P | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV99726303; called by muse, mutect2
- KNL1 | c.6581C>T p.S2194F (on ENST00000346991 / NM_170589.5; = p.S2168F on NM_144508.5) | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs1309144260, COSV61152057; called by muse, mutect2, varscan2
- KPNA1 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100724351; called by muse, mutect2, varscan2
- KPNA2 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0.028); catalogued as COSV100388867; called by muse, mutect2, varscan2
- KRT25 | c.734G>A p.G245E | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56444280; called by muse, mutect2, varscan2
- KRT25 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as rs529728231, COSV100380035; called by muse, mutect2, varscan2
- KRT3 | c.1225G>A p.D409N | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs891971466, COSV100527245; called by muse, mutect2, varscan2
- KRT34 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs866265957, COSV101222713, COSV67449443; called by muse, varscan2
- KRT35 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 43/73 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV55844474, COSV99877892; called by muse, mutect2, varscan2
- KRT7 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV99230210; called by muse, mutect2, varscan2
- KRT75 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99359577; called by muse, mutect2, varscan2
- KRT9 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1241387766, COSV55853262; called by muse, mutect2, varscan2
- KRTAP1-5 | c.173C>A p.S58Y | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.538); catalogued as COSV100721397; called by muse, mutect2, varscan2
- KRTAP10-1 | c.776A>G p.Q259R | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.752); catalogued as COSV100555170; called by muse, mutect2, varscan2
- KRTAP10-7 | c.263C>T p.S88L | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs1555928481, COSV100170298; called by muse, mutect2, varscan2
- L1TD1 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.274); catalogued as rs778590430, COSV63133564; called by muse, mutect2, varscan2
- L3MBTL4 | c.835C>T p.Q279* | Nonsense Mutation (SNP) | VAF 27/64 reads (42%) | catalogued as COSV99034579, COSV99530655; called by muse, varscan2
- LAMA1 | c.9005G>A p.S3002N | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT tolerated (0.36); PolyPhen benign (0.014); catalogued as COSV101057454; called by muse, mutect2, varscan2
- LARP1 | c.3085C>T p.P1029S (on ENST00000518297 / NM_033551.3; = p.P952S on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV100304024; called by muse, mutect2, varscan2
- LARP7 | c.598T>A p.F200I | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100135293; called by muse, mutect2, varscan2
- LCA5L | c.517C>T p.Q173* | Nonsense Mutation (SNP) | VAF 31/66 reads (47%) | catalogued as COSV99903848; called by muse, mutect2, varscan2
- LCE3D | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.555); catalogued as COSV100909862, COSV100909869; called by muse, mutect2, varscan2
- LCE3E | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 96/136 reads (71%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.018); catalogued as COSV100909967, COSV64231892; called by muse, mutect2, varscan2
- LCK | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs761633690, COSV100288034; called by muse, mutect2, varscan2
- LCOR | c.1433C>T p.P478L | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99617118; called by muse, mutect2, varscan2
- LCT | c.4132C>T p.P1378S | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV51551548; called by muse, mutect2, varscan2
- LCT | c.2254C>T p.L752F | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV51551677; called by muse, mutect2, varscan2
- LDAH | c.587T>C p.L196S | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.3); catalogued as COSV99425860; called by muse, mutect2, varscan2
- LDB2 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100454587; called by muse, mutect2, varscan2
- LGI4 | c.1498G>A p.V500M | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100032875; called by mutect2, varscan2
- LGSN | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 55/59 reads (93%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV65726500; called by muse, mutect2, varscan2
- LIG3 | c.173C>T p.S58L | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV52011395; called by muse, mutect2, varscan2
- LILRA2 | c.755G>A p.R252K | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.383); catalogued as rs538477847, COSV99253833; called by muse, mutect2, varscan2
- LIN54 | c.1265C>T p.P422L | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs1350717626, COSV100464930; called by muse, mutect2, varscan2
- LMNA | c.1113G>A p.M371I | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.349); catalogued as COSV100738813; called by muse, mutect2, varscan2
- LONP2 | c.2413G>T p.E805* | Nonsense Mutation (SNP) | VAF 32/55 reads (58%) | catalogued as COSV53521305; called by muse, mutect2, varscan2
- LPO | c.2126C>T p.S709L | Missense Mutation (SNP) | VAF 33/48 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV99229240; called by muse, mutect2, varscan2
- LRFN2 | c.2231C>T p.P744L | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT tolerated (0.33); PolyPhen benign (0.026); catalogued as COSV57823512; called by muse, mutect2, varscan2
- LRIT3 | c.730C>T p.Q244* | Nonsense Mutation (SNP) | VAF 37/94 reads (39%) | catalogued as rs375217997; called by muse, mutect2, varscan2
- LRP1B | c.11762C>T p.S3921L | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT tolerated (0.43); PolyPhen benign (0.162); catalogued as COSV101259772; called by muse, mutect2, varscan2
- LRP1B | c.3563C>T p.S1188F | Missense Mutation (SNP) | VAF 44/82 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV67256525; called by muse, varscan2
- LRP1B | c.3530C>T p.S1177L | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs377518986; called by muse, varscan2
- LRP1B | c.2893C>T p.P965S | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV101253958, COSV101259775; called by muse, mutect2, varscan2
- LRP1B | c.2689C>T p.R897C | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs766736610, COSV63341701; called by muse, mutect2, varscan2
- LRP1B | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs776305678, COSV67188037; called by muse, mutect2, varscan2
- LRP1B | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.66); PolyPhen benign (0.055); catalogued as COSV67267767; called by muse, mutect2, varscan2
- LRP6 | c.784C>T p.H262Y | Missense Mutation (SNP) | VAF 119/196 reads (61%) | SIFT tolerated (0.72); PolyPhen benign (0.234); catalogued as rs757657531, COSV99744236; called by muse, mutect2, varscan2
- LRPPRC | c.3874C>T p.L1292F | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.037); catalogued as rs1157831555, COSV99581313; called by muse, mutect2
- LRRC1 | c.788-1G>A p.X263_splice | Splice Site (SNP) | VAF 24/99 reads (24%) | catalogued as rs1170720274, COSV63829947; called by muse, mutect2, varscan2
- LRRC15 | c.701G>A p.G234E | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV100752889; called by muse, mutect2, varscan2
- LRRC15 | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); catalogued as rs761508015, COSV100752892; called by muse, mutect2, varscan2
- LRRC30 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT tolerated (0.64); PolyPhen benign (0.024); catalogued as COSV67301271; called by muse, mutect2, varscan2
- LRRC4C | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs1032228641, COSV99539362; called by muse, mutect2, varscan2
- LRRC55 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.899); catalogued as rs758123914, COSV73006865; called by muse, mutect2, varscan2
- LRRC6 | c.17A>G p.E6G | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99138432; called by muse, varscan2
- LRRC8B | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100446658; called by muse, mutect2, varscan2
- LRRIQ3 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.087); catalogued as rs866672669, COSV63041491; called by muse, mutect2, varscan2
- LRRN4 | c.1552G>A p.E518K | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT tolerated (0.67); PolyPhen benign (0.006); catalogued as rs1271817263, COSV101125506; called by muse, mutect2, varscan2
- LRRTM3 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63660810, COSV63663976; called by muse, mutect2, varscan2
- LSMEM2 | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100269781; called by muse, mutect2, varscan2
- LY75 | c.3377G>C p.S1126T | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as COSV99716895; called by muse, mutect2, varscan2
- LYST | c.11174G>T p.G3725V | Missense Mutation (SNP) | VAF 59/106 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101090120; called by muse, mutect2, varscan2
- MACROD2 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs778184364, COSV53987529; called by muse, mutect2, varscan2
- MADD | c.2174C>G p.T725R | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as COSV100211877; called by muse, mutect2, varscan2
- MAGEA10 | c.974C>T p.S325F | Missense Mutation (SNP) | VAF 78/81 reads (96%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV99726876; called by muse, mutect2, varscan2
- MAGEA4 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 44/46 reads (96%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.886); catalogued as COSV99367682; called by muse, mutect2, varscan2
- MAGEC3 | c.1543G>A p.D515N | Missense Mutation (SNP) | VAF 83/86 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100025416, COSV100025971; called by muse, varscan2
- MAGEC3 | c.1603G>A p.G535R | Missense Mutation (SNP) | VAF 72/75 reads (96%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.888); catalogued as rs766722987, COSV100025973; called by muse, varscan2
- MAML1 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.82); PolyPhen benign (0.012); catalogued as rs578168072, COSV99483325; called by muse, mutect2, varscan2
- MAP3K2 | c.945T>A p.S315R | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.38); PolyPhen benign (0.374); catalogued as COSV100789379; called by muse, mutect2, varscan2
- MAP3K21 | c.3085G>A p.E1029K | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.141); catalogued as COSV64042039, COSV64042476; called by muse, mutect2, varscan2
- MAP3K7CL | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 62/142 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99726851; called by muse, mutect2, varscan2
- MAPK8IP1 | c.1201G>A p.G401R | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs368904071, COSV99571431; called by muse, mutect2, varscan2
- MAPKAP1 | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1360705323, COSV99785606; called by muse, mutect2, varscan2
- MARCHF11 | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1448557798, COSV100198204; called by muse, mutect2, varscan2
- MAST4 | c.1746G>A p.G582= (on ENST00000403625 / NM_001164664.2; = p.G393= on NM_015183.3) | Splice Region (SNP) | VAF 13/25 reads (52%) | catalogued as COSV99845472; called by muse, mutect2, varscan2
- MATR3 | c.2252C>T p.A751V | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100735301; called by muse, mutect2, varscan2
- MBD3L1 | c.160C>A p.Q54K | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.269); catalogued as COSV99978041; called by muse, mutect2, varscan2
- MBD6 | c.1337C>T p.S446F | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100851795; called by muse, mutect2, varscan2
- MBTPS1 | c.2078T>C p.L693S | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1183605845, COSV100597752; called by muse, mutect2, varscan2
- MCF2 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 55/60 reads (92%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV100644764, COSV100645034; called by muse, mutect2, varscan2
- MDN1 | c.6377G>A p.R2126K | Missense Mutation (SNP) | VAF 37/43 reads (86%) | SIFT tolerated (0.28); PolyPhen benign (0.029); catalogued as COSV101021739; called by muse, mutect2, varscan2
- MECOM | c.2767G>A p.E923K (on ENST00000468789 / NM_001105078.4; = p.E1111K on NM_004991.4) | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV99243719, COSV99245217; called by muse, mutect2, varscan2
- MECOM | c.772C>T p.P258S (on ENST00000468789 / NM_001105078.4; = p.P446S on NM_004991.4) | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.996); catalogued as rs267599686, COSV52959125; called by muse, mutect2, varscan2
- MED13 | c.4424C>T p.S1475F | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT tolerated (0.71); PolyPhen benign (0.1); catalogued as COSV101181291; called by muse, mutect2, varscan2
- MED25 | c.827G>A p.G276E | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100457886; called by muse, mutect2, varscan2
- MEFV | c.1611G>A p.R537= | Splice Region (SNP) | VAF 44/91 reads (48%) | catalogued as rs1360467819, COSV99561172; called by muse, mutect2, varscan2
- MET | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV100577327, COSV59256027; called by muse, mutect2, varscan2
- METTL7A | c.317T>A p.F106Y | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as COSV100153716; called by muse, mutect2, varscan2
- MFGE8 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV51558214; called by muse, mutect2, varscan2
- MFSD11 | c.496+1G>A p.X166_splice | Splice Site (SNP) | VAF 52/132 reads (39%) | catalogued as COSV100334218; called by muse, mutect2, varscan2
- MFSD6L | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.966); catalogued as rs758358808, COSV100266801; called by muse, mutect2, varscan2
- MGAM | c.1379C>T p.S460F | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV101527712; called by muse, mutect2, varscan2
- MICAL2 | c.4249G>A p.E1417K | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.097); catalogued as COSV99812174; called by muse, mutect2, varscan2
- MICAL2 | c.4643C>T p.S1548F | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.609); catalogued as rs1177583100, COSV99812176; called by muse, mutect2, varscan2
- MID1 | c.1019C>T p.S340F | Missense Mutation (SNP) | VAF 36/36 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.396); catalogued as COSV100452677; called by muse, mutect2, varscan2
- MINAR1 | c.1325C>T p.S442F | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as rs1228331831, COSV100549162; called by muse, mutect2, varscan2
- MINDY4 | c.2003C>T p.P668L | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99519174; called by muse, mutect2, varscan2
- MKI67 | c.3214C>T p.P1072S | Missense Mutation (SNP) | VAF 106/241 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as rs759941205, COSV100896912; called by muse, mutect2, varscan2
- MME | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.124); catalogued as COSV100852229; called by muse, mutect2, varscan2
- MMP25 | c.345G>A p.W115* | Nonsense Mutation (SNP) | VAF 40/85 reads (47%) | catalogued as COSV100339584; called by muse, mutect2
- MON2 | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1205807330, COSV99743351; called by muse, mutect2, varscan2
- MOS | c.469C>T p.H157Y | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100322973; called by muse, mutect2, varscan2
- MPP6 | c.1391T>C p.L464S | Missense Mutation (SNP) | VAF 61/114 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99757782; called by muse, mutect2, varscan2
- MPP7 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as rs1021400851, COSV100517789; called by muse, mutect2, varscan2
- MRGPRX1 | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 56/176 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as rs771831053, COSV57106637; called by muse, mutect2
- MRGPRX4 | c.47A>G p.N16S | Missense Mutation (SNP) | VAF 58/127 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.285); catalogued as rs768996432, COSV100049829; called by muse, mutect2, varscan2
- MROH2B | c.3874G>A p.E1292K | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as COSV68183148; called by muse, mutect2, varscan2
- MROH2B | c.2362G>A p.D788N | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as COSV101270882; called by muse, mutect2, varscan2
- MROH2B | c.509G>A p.R170K | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs769024339, COSV101270636, COSV101270883; called by muse, mutect2, varscan2
- MS4A10 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV57632681; called by muse, mutect2, varscan2
- MSR1 | c.926G>A p.G309E | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1174944723, COSV100027877; called by muse, mutect2, varscan2
- MSR1 | c.925G>A p.G309R | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100027880; called by muse, mutect2, varscan2
- MSR1 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 94/165 reads (57%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs13306549, COSV50508538; called by muse, mutect2, varscan2
- MTCL1 | c.4199C>T p.P1400L (on ENST00000306329 / NM_001378206.1; = p.P1081L on NM_015210.4) | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV60411044; called by muse, mutect2, varscan2
- MTMR7 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 59/130 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.253); catalogued as COSV99472697; called by muse, mutect2, varscan2
- MTOR | c.5723C>T p.T1908I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100816597; called by muse, mutect2, varscan2
- MTTP | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.239); catalogued as COSV55508051; called by muse, mutect2, varscan2
- MTUS2 | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs780128229, COSV101462344; called by muse, mutect2, varscan2
- MUC13 | c.440C>T p.T147I | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.047); catalogued as COSV100222478; called by muse, mutect2, varscan2
- MUC16 | c.40550C>T p.P13517L | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.953); catalogued as rs367916400; called by muse, mutect2, varscan2
- MUC16 | c.39133G>C p.G13045R | Missense Mutation (SNP) | VAF 62/108 reads (57%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.009); catalogued as COSV101201152, COSV67443820; called by muse, varscan2
- MUC16 | c.38407C>T p.P12803S | Missense Mutation (SNP) | VAF 85/180 reads (47%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.021); catalogued as COSV101201156; called by muse, mutect2, varscan2
- MUC16 | c.33190C>T p.P11064S | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.047); catalogued as COSV101201159; called by muse, mutect2, varscan2
- MUC16 | c.18940G>A p.E6314K | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.549); catalogued as COSV67457320; called by muse, mutect2, varscan2
- MUC16 | c.12173C>T p.S4058F | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.076); catalogued as COSV101198926; called by muse, varscan2
- MUC16 | c.4051G>A p.E1351K | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); catalogued as COSV67467202; called by muse, mutect2, varscan2
- MUC16 | c.517G>A p.G173S | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.182); catalogued as COSV101201161; called by muse, mutect2, varscan2
- MUC20 | c.1330C>T p.L444F | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as rs781689081, COSV100291460; called by muse, mutect2, varscan2
- MUC6 | c.2911C>T p.P971S | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as COSV70149880; called by muse, mutect2, varscan2
- MUC6 | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs746495508, COSV101424739; called by muse, mutect2, varscan2
- MUC7 | c.512C>T p.T171I | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.224); catalogued as COSV100512369; called by muse, mutect2, varscan2
1,465 further variants in this file (680 protein-altering or splice-affecting, 726 silent, 59 other) are not listed here.
